Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4713, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4713-01A (Primary Tumor).

FINAL DIAGNOSIS:

KIDNEY, RIGHT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, 13.5 CM IN GREATEST DIMENSION.
- B. FUHRMAN NUCLEAR GRADE II/IV.
- C. TUMOR EXTENDS BEYOND THE RENAL CAPSULE INTO PERINEPHRIC FAT, ON BOTH MACROSCOPIC AND MICROSCOPIC EXAMINATION.
- D. INVASION OF THE RENAL VEIN AND IT'S BRANCHES IS IDENTIFIED.
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. THE RENAL VEIN MARGIN IS INVOLVED BY TUMOR AND CONTAINS TUMOR THROMBUS.
- G. ARTERIAL, URETERIC AND SOFT TISSUE MARGINS ARE FREE OF TUMOR
- H. THE NON-NEOPLASTIC KIDNEY SHOWS CHRONIC GLOMERULONEPHRITIS AND MODERATE RENAL HYPERTENSIVE VASCULAR DISEASE.
- I. THE ADRENAL GLAND IS FREE OF TUMOR.
- J. TNM STAGE: pT3b NX MX.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Radical nephrectomy

LATERALITY: Right

TUMOR SITE: Upper pole

Middle

FOCALITY: Unifocal

TUMOR SIZE: Greatest dimension: 13.5 cm

Additional dimensions: 9.5 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor extension into perinephric tissues

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G2

PATHOLOGIC STAGING (pTNM): pT3b

pNX

Number of regional lymph nodes examined: 0

pMX

MARGINS: Margin(s) involved by invasive carcinoma

Renal vein margin

ADRENAL GLAND: Uninvolved by tumor

VENOUS (LARGE VESSEL) INVASION (V): Present

LYMPHATIC (SMALL VESSEL) INVASION (L): Absent

ADDITIONAL PATHOLOGIC FINDINGS: Glomerular disease (type): Glomerulosclerosis

Source: NCI Genomic Data Commons file 8265703c-2a3f-4bdd-a139-3ee78a48155f (TCGA-B0-4713.07279C0B-0D5D-4011-B516-BD6B4976AB5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).